Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A3XF, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A3XF-01A (Primary Tumor).

Procurement Date Laterality:

Path Report:SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, trunk

Tumor size: 1.5 x 0 x 2 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade:

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Breslow's depth 10 mm.

ICD-O-3

melanoma, NOS

8720/3

site: CQCF-skin NOS

C44.9

path: skin, trunk

C44.5

5-17-12

RO

For Malignancy History		☒
Reviewed Date	5/10/12	

Source: NCI Genomic Data Commons file 893a723d-c091-497e-9e3e-b5ba8f2e8441 (TCGA-EB-A3XF.33B18494-DFE3-45C4-9EDB-75A8747632D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).